Gene-level copy-number profile of specimen HCM-BROD-0041-C64-85A from HCMI case HCM-BROD-0041-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 7.3 years (2,655 days).
Specimen HCM-BROD-0041-C64-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 19.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d722640c-17e4-49b0-9f54-721faa0bd32c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0041-C64-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/75e0ef0a-8f0b-488e-8637-57c05b06da1e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,050; copy number 2: 49,455; copy number 3: 3,634; copy number 4: 1,208; copy number 5: 46; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 48 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,338,287–57,207,459, 30 genes, copy number 5: AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1.
- chr4:58,103,147–58,118,070, 2 genes, copy number 6: SRIP1, AC096725.1.
- chr17:81,509,971–81,707,517, 16 genes, copy number 5 (within-gene range 3–5): ACTG1, AC139149.1, FSCN2, FAAP100, NPLOC4, Y_RNA, TSPAN10, PDE6G, OXLD1, CCDC137, ARL16, HGS, MIR6786, AC139530.3, AC139530.1, MRPL12.

Autosomal genes at a single copy (total copy number 1): 4,050. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
